Somatic mutation profile of tumor specimen TARGET-30-PANIPC-06A (aliquot TARGET-30-PANIPC-06A-01W) from TARGET case TARGET-30-PANIPC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.5 years (921 days).
Specimen TARGET-30-PANIPC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bdebfde-7193-401d-b35b-72f1d747e9fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANIPC-10A (Blood Derived Normal), aliquot TARGET-30-PANIPC-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/779b5315-c9c5-429c-9268-d8801699cec3

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Nonsense Mutation 12, Splice Region 1, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- ABCF1 | c.2125G>A p.E709K (on ENST00000326195 / NM_001025091.2; = p.E671K on NM_001090.3) | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV58227746; called by mutect2, varscan2
- APOL4 | c.521C>A p.A174D (on ENST00000352371 / NM_145660.2; = p.A171D on NM_030643.4) | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV60653924; called by muse, mutect2
- BMERB1 | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV55505605; called by muse, varscan2
- CLCN4 | c.2239G>A p.A747T | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as COSV66464993; called by muse, mutect2, varscan2
- CLDN25 | c.332G>T p.R111I | Missense Mutation (SNP) | VAF 146/397 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV71620403; called by mutect2, varscan2
- COL5A1 | c.3445G>T p.V1149L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as rs966038747; called by muse, mutect2
- COX11 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 42/151 reads (28%) | catalogued as COSV54802442; called by muse, mutect2, varscan2
- CPNE9 | c.1007C>A p.A336E | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56067526; called by muse, mutect2, varscan2
- CWC22 | c.1649T>G p.M550R | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV55426326; called by muse, mutect2, varscan2
- DLEC1 | c.2824G>T p.E942* | Nonsense Mutation (SNP) | VAF 17/316 reads (5%) | catalogued as rs1355256601; called by muse, mutect2
- DZIP3 | c.3518G>T p.C1173F | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1268708716; called by muse, mutect2
- EP300 | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.045); catalogued as rs377517076; called by muse, mutect2, varscan2
- FAT2 | c.1917G>T p.K639N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs1187645912, COSV55812599; called by muse, mutect2, varscan2
- FBP2 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs762728707, COSV64694233; called by muse, mutect2, varscan2
- FGFR1 | c.784C>G p.P262A (on ENST00000447712 / NM_023110.3; = p.P260A on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV58327861; called by muse, mutect2
- IKZF2 | c.237C>A p.S79R | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.073); catalogued as COSV59577842; called by muse, mutect2
- KLHL6 | c.1017C>A p.C339* | Nonsense Mutation (SNP) | VAF 42/366 reads (11%) | catalogued as COSV58064320; called by muse, mutect2, varscan2
- LCE1E | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 186/286 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64219472; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as COSV53275120; called by muse, mutect2, varscan2
- MAP2 | c.2388C>A p.Y796* | Nonsense Mutation (SNP) | VAF 88/235 reads (37%) | catalogued as COSV52280096, COSV52282081; called by muse, mutect2, varscan2
- MECOM | c.2285G>T p.R762I (on ENST00000468789 / NM_001105078.4; = p.R950I on NM_004991.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV52958905; called by muse, mutect2
- NCAN | c.1622G>T p.W541L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV53046370; called by muse, mutect2
- OR2C1 | c.479C>A p.S160* | Nonsense Mutation (SNP) | VAF 140/312 reads (45%) | catalogued as COSV59239508; called by muse, mutect2, varscan2
- PTPRN2 | c.2935G>T p.E979* | Nonsense Mutation (SNP) | VAF 18/470 reads (4%) | catalogued as COSV67030743; called by muse, mutect2
- PUM1 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV57081103; called by muse, mutect2
- SIRPB2 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV63122871; called by muse, mutect2, varscan2
- SMARCC2 | c.3043C>A p.Q1015K | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV53237034; called by muse, mutect2, varscan2
- SOX15 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV51467371; called by muse, mutect2
- TAF6 | c.1661T>C p.L554P | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as rs1353000293, COSV59840499; called by muse, mutect2, varscan2
- TGM2 | c.1866C>A p.F622L | Missense Mutation (SNP) | VAF 70/409 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV63930995; called by muse, mutect2, varscan2
- UBL7 | c.852C>A p.S284R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV63705654; called by muse, mutect2, varscan2
- WDR49 | c.1111G>T p.A371S (on ENST00000308378 / NM_001366158.1; = p.A712S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV57701537, COSV57704188; called by muse, mutect2, varscan2
- ZMYM5 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 33/434 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV61990408; called by muse, mutect2
- AARS2 | c.2855dup p.K953Qfs*17 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- C17orf98 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CCDC62 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 32/732 reads (4%) | called by muse, mutect2
- CDV3 | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- FLG | c.9605C>A p.S3202* | Nonsense Mutation (SNP) | VAF 29/480 reads (6%) | called by muse, mutect2
- GRB10 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); called by muse, mutect2
- HEATR5A | c.4031C>A p.A1344E | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HERC2 | c.7811A>C p.D2604A | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MOB1A | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 42/433 reads (10%) | called by muse, mutect2
- NKAIN1 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.989); called by muse, mutect2
- PRAMEF17 | c.285C>A p.P95= | Splice Region (SNP) | VAF 34/48 reads (71%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 44/656 reads (7%) | called by muse, mutect2
- TCERG1 | c.3271G>T p.E1091* | Nonsense Mutation (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- THUMPD3 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 50/535 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- TOGARAM1 | c.695C>A p.A232D | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UBE2N | c.419-1G>T p.X140_splice | Splice Site (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- ZNF182 | c.927C>A p.Y309* | Nonsense Mutation (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- ZNF776 | c.432C>A p.S144R | Missense Mutation (SNP) | VAF 13/337 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2
- C12orf66 | c.657G>T p.A219= | Silent (SNP) | VAF 44/269 reads (16%) | catalogued as COSV61322261; called by muse, mutect2, varscan2
- C3 | c.2151C>T p.G717= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV55568151; called by muse, mutect2, varscan2
- CAND1 | c.312C>T p.D104= | Silent (SNP) | VAF 103/514 reads (20%) | called by mutect2, varscan2
- COQ4 | c.339C>A p.G113= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV55956334; called by muse, mutect2, varscan2
- DHX37 | c.1917G>A p.G639= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as COSV58131517; called by muse, mutect2, varscan2
- EMC6 | c.267C>A p.L89= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs1183918634; called by muse, mutect2
- FBN2 | c.7674T>C p.C2558= | Silent (SNP) | VAF 134/437 reads (31%) | catalogued as COSV52490799; called by muse, mutect2, varscan2
- FBN3 | c.6750C>T p.C2250= | Silent (SNP) | VAF 49/79 reads (62%) | catalogued as COSV54452610; called by muse, mutect2, varscan2
- KCNQ3 | c.562C>A p.R188= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as COSV66463240, COSV66465621; called by muse, mutect2, varscan2
- KMT2C | c.10938G>T p.V3646= | Silent (SNP) | VAF 150/332 reads (45%) | catalogued as COSV51278010, COSV51503663; called by muse, mutect2, varscan2
- MYO1F | c.1026C>T p.N342= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs748189585, COSV57791606; called by muse, mutect2, varscan2
- NUP210L | c.2709G>T p.V903= | Silent (SNP) | VAF 44/599 reads (7%) | called by muse, mutect2
- PCDH12 | c.3177G>A p.A1059= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs375614422; called by muse, mutect2, varscan2
- RGL3 | c.1557C>A p.I519= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV66506216; called by muse, mutect2, varscan2
- RUBCN | c.1530G>A p.K510= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as rs375842322; called by muse, mutect2, varscan2
- SLC13A4 | c.1575C>A p.I525= | Silent (SNP) | VAF 89/995 reads (9%) | called by muse, mutect2
- SNAP47 | c.831C>T p.V277= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV59916783; called by muse, mutect2, varscan2
- SNORD115-4 | n.55C>A | RNA (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
